Gene-level copy-number profile of tumor specimen C3L-08791-01 from CPTAC case C3L-08791, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 54.5 years (19,924 days).
Specimen C3L-08791-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7380d67c-3c8b-4564-af3d-a32eba542768.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-08791-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/0eb5307f-c65e-4a4b-8471-52f81a0cbec7

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 1,150; copy number 2: 19,098; copy number 3: 20,765; copy number 4: 12,626; copy number 5: 2,965; copy number 6: 843; copy number 7: 453; copy number 8: 36; copy number 9: 207; copy number 10: 25; copy number 11: 2; copy number 12: 27; copy number 14: 19; copy number 15: 1; copy number 16: 17; copy number 17: 10; copy number 20: 32; copy number 25: 18; copy number 29: 99.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:106,436,415–106,461,055, 4 genes (within-gene range 0–2): AC244452.1, IGHVII-40-1, IGHV3-41, HOMER2P1.
- chr14:106,470,264–106,470,800, 1 gene (within-gene range 0–2): IGHV3-43.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 946 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,811,359–143,825,837, 1 gene, copy number 8: AC239798.1.
- chr5:16,067,139–17,276,843, 22 genes, copy number 8: MARCHF11, MARCHF11-AS1, AC092335.1, NACAP6, LINC02150, AC020980.1, ZNF622, RETREG1, AC024588.1, AC022113.1, Y_RNA, MYO10, RNA5SP179, RPS26P28, RNU6-660P, BASP1, BASP1-AS1, AC026790.1, Y_RNA, RNA5SP180, DCAF13P2, RNU6-1003P.
- chr5:34,651,457–41,895,599, 111 genes, copy number 7–8 (broad region; genes not listed).
- chr5:43,336,164–45,696,498, 29 genes, copy number 7–17: AC114947.1, CCL28, TMEM267, AC114956.2, C5orf34, EEF1A1P19, C5orf34-AS1, AC114956.1, PAIP1, NNT-AS1, AC010435.1, AMD1P3, NNT, RPL29P12, AC104119.1, RNU6-381P, FGF10, FGF10-AS1, LINC02224, AC093292.1, RN7SL383P, MRPS30-DT, AC093297.1, MRPS30, AC093297.2, AC114954.1, HCN1, AC117529.2, AC117529.1.
- chr8:65,155,407–71,228,629, 98 genes, copy number 7 (broad region; genes not listed).
- chr8:79,259,402–86,818,558, 137 genes, copy number 7 (broad region; genes not listed).
- chr13:21,790,537–21,878,256, 2 genes, copy number 7: RN7SL766P, LINC00424.
- chr13:25,095,868–25,366,155, 12 genes, copy number 9: PABPC3, AL359757.2, AMER2, LINC01053, LINC00463, AL359757.1, LINC01076, RPL23AP69, MTMR6, AL590787.1, NUP58, ELOBP1.
- chr13:27,017,554–32,954,401, 113 genes, copy number 9 (broad region; genes not listed).
- chr13:33,355,206–41,132,802, 104 genes, copy number 7–9 (within-gene range 5–9) (broad region; genes not listed).
- chr13:64,958,097–72,756,198, 57 genes, copy number 7 (within-gene range 5–7): LGMNP1, STARP1, HNRNPA3P5, LINC01052, AL158038.1, MIR548X2, MIR4704, TRIM60P19, PCDH9, PCDH9-AS1, RNU7-87P, PCDH9-AS2, PCDH9-AS3, PCDH9-AS4, AL160254.1, RPSAP53, LINC00364, BCRP9, NPM1P22, OR7E111P, OR7E33P, ELL2P3, HNRNPA1P18, RPL37P21, RPS3AP52, RPL12P34, RN7SL761P, LINC00550, LINC02342, ZDHHC20P4, SNRPFP3, LINC00383, SRSF1P1, KLHL1, RNY3P10, PSMC1P13, ATXN8OS, AL160391.1, RNU6-54P, AL445264.1, MTCL1P1, LINC00348, RABEPKP1, DACH1, H3P36, RPL21P109, RPL35AP31, RPS10P21, AL139003.1, RPL18AP17, AL139003.2, AL356754.2, AL356754.1, RPL21P110, RNU6-80P, MZT1, BORA.
- chr17:36,861,674–38,405,593, 44 genes, copy number 10–14: LHX1-DT, LHX1, AC243773.1, AATF, AC243773.2, AC244093.4, MIR2909, AC244093.3, AC244093.5, ACACA, AC244093.1, HMGB1P24, AC244093.2, C17orf78, AC243654.3, TADA2A, AC243654.1, AC243654.2, DUSP14, SYNRG, AC243585.2, DDX52, MIR378J, AC243571.2, AC243585.1, HNF1B, AC243571.1, YWHAEP7, RNU6-489P, TBC1D3K, 5S_rRNA, TBC1D3L, TBC1D3D, TBC1D3C, AC233968.1, Y_RNA, TBC1D3E, RNA5SP526, TBC1D3, NPEPPSP1, Y_RNA, MRPL45, GPR179, SOCS7.
- chr17:38,825,838–42,021,376, 194 genes, copy number 12–29 (within-gene range 2–29) (broad region; genes not listed).
- chr20:19,756,390–21,115,197, 22 genes, copy number 7–11: AL121761.1, RIN2, RPL12P12, NAA20, CRNKL1, CFAP61, AL035454.1, AL049648.1, RPL17P1, CFAP61-AS1, RN7SL690P, AL161658.1, INSM1, RALGAPA2, EIF4E2P1, LLPHP1, RN7SL607P, MRPS11P1, AL133465.1, LINC00237, AL121759.2, RPL24P2.

Autosomal genes at a single copy (total copy number 1): 1,149. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
